Surgical pathology report (de-identified scan), TCGA case TCGA-DD-AADR, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-AADR-01A (Primary Tumor).

[page 1 of 2]
UUIID:1037C8D1-A07D-4FEA-84AF-364335AC37E9

CLINICAL DIAGNOSIS: HCC

Specimen : Liver

Gross Photo .

GROSS:

Specimen:

Liver: 3.0 x 2.3 x 2.0 cm, 15.0 gm, unfixed

Tumor location: segment 4

Tumor number: one

Tumor size: 1.2 x 1.3 x 1.1 cm

Satellite nodule: no

Gross type:

HCC: vaguely nodular

Tumor necrosis: no

Hemorrhage/peliosis: no

Portal vein invasion: no

Bile duct invasion: no

ICD O-3

Carcinoma, hepatocellular NOS
8170/3

Site: Liver C22.0

Q25/20/14

Gross photo present.

Blocks

T1-2, tumor mass x 2

RM, resection margin x 1

MICROSCOPIC:

Hepatocellular carcinoma: yes

Differentiation

The worst differentiation III

The major differentiation III

Histologic type: trabecular

Cell type: hepatic and focal clear

Fatty change: yes, < 20 %

Cholangiocarcinoma: no

Combined hepatocellular and cholangiocarcinoma: no

Fibrous capsule formation: complete capsule

Capsular infiltration: no

Septum formation: no

Surgical resection margin invasion: cannot be assessed (see NOTE)

Serosal invasion: no

Portal vein invasion: no

[page 2 of 2]
Bile duct invasion: no
Hepatic vein invasion: no
Hepatic artery invasion: no

Non-tumor liver pathology
Chronic hepatitis: yes
Etiology: HBV
Grade, lobular: minimal
Grade, portoperiportal: mild
Stage (fibrosis): cirrhosis
Cirrhosis: mixed
Dysplastic nodule: low grade
Ductal epithelial dysplasia: no
Other liver diseases: no

SPECIAL STAIN:

Trichrome stain shows thick fibrotic bands surrounding regenerative nodules.

IMMUNOHISTOCHEMISTRY: Hepatocyte (+), CK19 (-)

NOT reported. Gross:

Liver, resection, hepatocellular carcinoma, cirrhosis
T56000, P17, M81703, M49500

DIAGNOSIS:

Liver, segment 4, laparoscopic wedge resection:
Hepatocellular carcinoma
Cirrhosis

NOTE:

Suggestion :

Source: NCI Genomic Data Commons file 2fab09b3-1679-44e1-aebb-52907770ef15 (TCGA-DD-AADR.1037C8D1-A07D-4FEA-84AF-364335AC37E9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).